Gene-level copy-number profile of tumor specimen TCGA-AA-A01F-01A from TCGA case TCGA-AA-A01F, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 72.0 years (26,298 days).
Specimen TCGA-AA-A01F-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.e2aefe45-12c7-4bba-af87-3cc1d42fd443.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-A01F-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 356 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8dd71035-54a2-4074-8dac-1570c16334af

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 5; copy number 2: 27,445; copy number 3: 24,856; copy number 4: 2,261; copy number 5: 3,500; copy number 6: 2,194; copy number 8: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-AA-A01F-01): tumor purity 0.89, ploidy 2.8, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:14,884,250–15,022,958, 4 genes: MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,136 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:208,266,059–208,270,667, 1 gene, copy number 8: AL606753.2.
- chr7:8,433,609–159,233,377, 2,811 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr12:31,111,652–31,252,597, 3 genes, copy number 5: AC024940.1, AC024940.4, AC024940.2.
- chr13:18,467,172–114,337,626, 1,391 genes, copy number 5–6 (broad region; genes not listed).
- chr17:36,116,177–36,177,510, 1 gene, copy number 8 (within-gene range 4–8): AC243829.2.
- chr20:25,985,210–64,313,132, 929 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
